Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5750, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5750-01A (Primary Tumor).

TCGA-CH-5750

Diagnosis

1. Predominantly moderately differentiated bilateral adenocarcinoma of the prostate, limited to the organ (Gleason 3+4=7 (Gleason 4: 20%)), mainly in the peripheral zone. Maximum tumor diameter 2.4 cm. Extraprostatic bilateral tumor growth in the region of the seminal vesicles.

Multifocal tumor involvement of perineural sheaths. Tumor-free surgical preparation margin. The additional immunohistological analysis of two representative tumor blocks also shows no evidence of tumorous vessel invasion.

In addition, numerous foci of a prostatic intraepithelial neoplasia (high-grade PIN) and signs of myoglandular prostatic hyperplasia. Urothelium of prostatic urethra without dysplasia. Tumor-free, regular seminal vesicles and seminal ducts.

2. Five tumor-free lymph nodes.

3. Two tumor-free lymph nodes.

Summary tumor classification (taking into account the frozen section analysis)
pT2c, max. tumor diameter 2.4 cm, Gleason 3+4=7 (Gleason 4: 20%), R0, pN0 (0/7).

Remark

Contact of tumor with the yellow-labeled preparation margin (frozen section analysis). The green/yellow-labeled surgical preparation margin is tumor-free.

Source: NCI Genomic Data Commons file 0b6d1f6e-2746-4945-8018-82dcefd81c58 (TCGA-CH-5750.4CBD15A8-2912-4A6D-BDC3-38A4AE4E1381.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).